Somatic mutation profile of tumor specimen TCGA-EO-A2CG-01A (aliquot TCGA-EO-A2CG-01A-12D-A17W-09) from TCGA case TCGA-EO-A2CG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 69.2 years (25,279 days).
Specimen TCGA-EO-A2CG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ac88fe7-3806-4947-83db-64384c5f08f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A2CG-10A (Blood Derived Normal), aliquot TCGA-EO-A2CG-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d5f94e1-3318-4dc1-883f-5cfa3595101c

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 28, Silent 11, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 17/22 reads (77%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs375338359, CM098494, COSV52690857, COSV52980226, COSV53438718; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.1270G>A p.V424M (on ENST00000372530 / NM_001198934.2; = p.V381M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as rs1247070752, COSV99766924; called by muse, mutect2, varscan2
- CNTNAP2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as rs370057104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs750097119, COSV99384786; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DOCK7 | c.6016G>C p.E2006Q (on ENST00000635253 / NM_001367561.1; = p.E1975Q on NM_033407.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99223619; called by muse, mutect2, varscan2
- HELB | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs370199105; called by muse, mutect2, varscan2
- HJURP | c.1538G>A p.R513K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV100982571; called by muse, mutect2, varscan2
- ITGAL | c.910T>A p.S304T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100776146; called by muse, mutect2, varscan2
- KCNQ2 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV60432240; called by muse, mutect2, varscan2
- MASP2 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754479514, COSV101280114; called by muse, mutect2, varscan2
- MMP26 | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV100332023; called by muse, mutect2, varscan2
- NKAIN3 | c.318G>T p.W106C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100132572; called by muse, mutect2, varscan2
- NLRP14 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs372852266; called by muse, mutect2, varscan2
- ODF2 | c.1240G>A p.E414K (on ENST00000434106 / NM_153433.2; = p.E390K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs1008126433, COSV100654494, COSV63548536; called by muse, mutect2, varscan2
- OR4C13 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101634152, COSV73648737; called by muse, mutect2, varscan2
- PCDH11X | c.3026C>G p.T1009S | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100009978, COSV100014223; called by muse, mutect2, varscan2
- PCDHGA12 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV99338886; called by muse, mutect2, varscan2
- PCM1 | c.4585C>T p.R1529C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs777036141, COSV59586431; called by muse, mutect2, varscan2
- PER3 | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as COSV100728258; called by muse, mutect2, varscan2
- PLCB1 | c.2693T>C p.I898T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100570049; called by muse, mutect2, varscan2
- PLCB4 | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99594795; called by muse, mutect2, varscan2
- POLA2 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV55483073; called by muse, mutect2, varscan2
- POTEH | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV100625013, COSV58883227; called by muse, mutect2, varscan2
- PRDM9 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs1425057806, COSV57002819, COSV57012319; called by muse, mutect2, varscan2
- THEM6 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.628); catalogued as rs764843549, COSV100278775; called by muse, mutect2, varscan2
- TNNI3K | c.1177+1G>A p.X393_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100436066; called by muse, mutect2, varscan2
- VILL | c.861C>A p.D287E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99378601; called by muse, mutect2, varscan2
- YWHAE | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.233); catalogued as COSV51983240, COSV51984459; called by muse, mutect2, varscan2
- ZNF226 | c.2189_2193del p.D730Vfs*3 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs745922674; called by pindel, varscan2
- ZNF268 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.092); catalogued as rs781577602, COSV57212380; called by muse, mutect2, varscan2
- IGKV1D-42 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CTNND1 | c.243A>C p.S81= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100649941; called by muse, mutect2, varscan2
- FLG2 | c.6147C>T p.H2049= | Silent (SNP) | VAF 63/163 reads (39%) | catalogued as rs146074268; called by muse, mutect2, varscan2
- HPS5 | c.105A>G p.L35= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs375494225; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIF26B | c.2550C>T p.S850= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs765221697, COSV100831884; called by muse, mutect2, varscan2
- LRRC43 | c.1120T>C p.L374= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1207982764, COSV100336625; called by muse, mutect2
- MUC4 | c.609G>A p.T203= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs566955429, COSV100640168; called by muse, mutect2, varscan2
- NRXN2 | c.2116C>A p.R706= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV55449452, COSV99633149; called by muse, mutect2, varscan2
- RGMA | c.360C>G p.P120= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100224241; called by muse, mutect2, varscan2
- STAT3 | c.627G>A p.A209= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs759225787, COSV52885125, COSV52888064; called by muse, mutect2, varscan2
- TXNRD1 | c.459C>T p.G153= (on ENST00000525566 / NM_001093771.3; = p.G55= on NM_003330.4) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100723369; called by muse, mutect2, varscan2
- ZBTB39 | c.447G>A p.S149= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs755063357, COSV100267976; called by muse, mutect2, varscan2
